CCDI case PBCVUM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3d7179b0-24ce-42bf-9008-e328ac1f65c8

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1NYI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1NZT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1O0L: Tissue type: Tumor; Specimen type: Solid Tissue.
